HCMI case HCM-EXPT-1168-C43 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/fa5791ff-50c5-4344-a9b5-df2db51f4c15

Demographics
Sex at birth: male; Year of birth: 1947.

Diagnoses (1; GDC holds 2 diagnosis records for this case, 1 of them empty or duplicates of those shown)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C43.9; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 68.9 years (25,181 days); Prior treatment: Yes.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Treatment intent type: Neoadjuvant.

Biospecimens (1 sample)
- Sample HCM-EXPT-1168-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
